Somatic mutation profile of tumor specimen TCGA-17-Z020-01A (aliquot TCGA-17-Z020-01A-01W-0746-08) from TCGA case TCGA-17-Z020, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6268811e-1d3c-433b-93c2-88ec69f3b499.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z020-11A (Solid Tissue Normal), aliquot TCGA-17-Z020-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6194e7af-11f6-4a25-85f3-bc98be3a7e14

The open-access MAF lists 124 somatic variants for this specimen: 91 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 30, Nonsense Mutation 7, Intron 1, RNA 1, In Frame Del 1, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB10 | c.536C>G p.T179R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as COSV60622165; called by muse, mutect2, varscan2
- ATP8B4 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99464528; called by muse, mutect2
- C6orf118 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1053205337, COSV57812202; called by muse, mutect2, varscan2
- CFAP43 | c.3493G>C p.E1165Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63853191; called by muse, mutect2
- CRACD | c.2590G>C p.A864P | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV51716230; called by muse, mutect2
- DAPK2 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1412716184; called by muse, mutect2, varscan2
- DAXX | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as COSV56467290; called by muse, mutect2
- DNAH2 | c.9797G>T p.R3266L | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs931986589, COSV101209158; called by muse, mutect2
- EPHA4 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.257); catalogued as COSV56043883; called by muse, mutect2, varscan2
- F5 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190555110, COSV100888985; called by muse, mutect2, varscan2
- HADHB | c.151A>T p.I51L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58544878; called by muse, mutect2, varscan2
- KIF21B | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100144596, COSV59754367, COSV59769096; called by muse, mutect2, varscan2
- LRRC55 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs755509162, COSV101546728; called by mutect2, varscan2
- MAGEC3 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs780409237, COSV100024904; called by muse, mutect2, varscan2
- MUC16 | c.13394C>A p.P4465H | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV101201916; called by muse, mutect2
- MUC17 | c.9182C>T p.P3061L | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV60282444; called by muse, mutect2
- NLRC3 | c.2318C>A p.A773D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57086597; called by muse, mutect2, varscan2
- OPCML | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV59406450; called by muse, mutect2, varscan2
- OR2C3 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV63574665; called by muse, mutect2, varscan2
- OR5D18 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV61738645; called by muse, mutect2
- PCDHA13 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs1554181508, COSV56543717; called by muse, mutect2, varscan2
- ROBO1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71397829; called by muse, mutect2
- RPS27L | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.863); catalogued as COSV58387844; called by muse, mutect2
- TRIM3 | c.1869A>T p.A623= | Splice Region (SNP) | VAF 6/52 reads (12%) | catalogued as COSV61982977; called by muse, mutect2
- TRPM6 | c.5460G>T p.E1820D | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV62513799; called by muse, mutect2
- TTC38 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV66843593; called by muse, mutect2
- UFD1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1244215037, COSV54244825; called by muse, mutect2, varscan2
- UQCC1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs746972839; called by muse, mutect2
- ADAMTS3 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ADCY8 | c.2344T>A p.Y782N | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADPRH | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- ARHGAP31 | c.2727G>T p.E909D | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARPC3 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- ATG3 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); called by mutect2, varscan2
- ATP8B4 | c.3230C>T p.A1077V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD3 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- CAMK4 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDADC1 | c.708A>G p.I236M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.251); called by mutect2, varscan2
- CEP290 | c.2096T>A p.L699Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CSTB | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EARS2 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by mutect2, varscan2
- F5 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM160B1 | c.2155A>T p.R719* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- FGA | c.812G>C p.R271P | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- FOCAD | c.4443G>T p.Q1481H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GZMK | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2
- HDAC9 | c.2452G>C p.D818H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HS3ST5 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- INTS8 | c.2689-1G>A p.X897_splice | Splice Site (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- KLF7 | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAP3K4 | c.4000G>T p.V1334F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MCTP2 | c.1802A>T p.Q601L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- MGAT5 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MIEN1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- NAA25 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.556); called by mutect2, varscan2
- NDST1 | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPHS1 | c.2303T>A p.I768N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- NUP188 | c.748A>C p.N250H | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR6C3 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTX1 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPC1 | c.1431G>C p.M477I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCED1A | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, varscan2
- PCNX2 | c.3515G>C p.R1172T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4B | c.339C>G p.S113R | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2
- POLR2C | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPM1H | c.1454G>T p.R485I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- PPP4R3B | c.2005G>A p.V669I (on ENST00000616407 / NM_001122964.3; = p.V584I on NM_020463.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2
- PRAMEF19 | c.778A>G p.S260G | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAD51 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ROCK1 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- SETBP1 | c.1325C>G p.T442S | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- SF3A1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SFTPB | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2
- SGO2 | c.768G>C p.Q256H | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- SLC34A2 | c.790_792del p.L264del | In Frame Del (DEL) | VAF 20/196 reads (10%) | called by mutect2, pindel
- SLC37A3 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by mutect2, varscan2
- SYMPK | c.632T>G p.I211S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TCF7L2 | c.1505C>G p.S502* (on ENST00000355995 / NM_001367943.1; = p.S479* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2, varscan2
- TMEM126A | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOGARAM1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TTF2 | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- UACA | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR2 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- WDFY3 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- WDR17 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- XIRP2 | c.7364C>G p.S2455C (on ENST00000628543; = p.S2630C on NM_152381.6) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ZFHX4 | c.7544A>G p.H2515R | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZKSCAN4 | c.853T>C p.C285R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.233); called by muse, mutect2
- ZNF599 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ACAN | c.4584C>T p.L1528= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs766660734; called by mutect2, varscan2
- ACHE | c.711C>A p.A237= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99574148; called by muse, mutect2
- ACKR2 | c.624C>T p.L208= | Silent (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2
- ADGRF4 | c.897G>T p.G299= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- AVL9 | c.1020G>A p.E340= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- CFHR1 | c.366C>T p.N122= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- COP1 | c.2013T>A p.L671= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- DNMT3B | c.687G>T p.V229= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV52420904; called by muse, mutect2
- FAM47A | c.1498C>A p.R500= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV60497293; called by muse, varscan2
- FAM47A | c.1344G>A p.R448= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs756806629; called by muse, mutect2, varscan2
- GATA5 | c.1110C>A p.A370= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- HLA-DRA | c.465A>T p.T155= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- KMT2D | c.5523C>G p.A1841= | Silent (SNP) | VAF 40/283 reads (14%) | called by muse, varscan2
- KMT2E | c.1962T>C p.F654= | Silent (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- LPA | c.1152C>A p.T384= | Silent (SNP) | VAF 29/1101 reads (3%) | catalogued as rs1461843784; called by muse, mutect2
- MYH4 | c.2895G>T p.L965= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- OR2T8 | c.30C>T p.F10= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs767508824, COSV60662671; called by muse, mutect2
- PCDHB10 | c.768C>A p.P256= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1183575523, COSV53378286, COSV99504739; called by muse, mutect2, varscan2
- PCDHB7 | c.1191C>A p.V397= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs782219371, COSV50758951; called by muse, mutect2, varscan2
- PFKFB2 | c.186C>T p.L62= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- PHF1 | c.1182C>T p.R394= (on ENST00000374516 / NM_024165.3; = p.Q391* on NM_002636.5) | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- RHBG | c.234C>T p.L78= | Silent (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- RYR2 | c.1281T>C p.N427= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs375691875, COSV104419363; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN8A | c.3324C>T p.L1108= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100634376; called by muse, mutect2
- SELPLG | c.214C>T p.L72= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- SERPINA3 | c.831C>T p.I277= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SMG1 | c.2037C>T p.I679= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- STRIP1 | c.2142G>A p.L714= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs775729700; called by muse, mutect2, varscan2
- TMEM117 | c.1254G>A p.L418= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs1449349558; called by muse, mutect2, varscan2
- ZFPL1 | c.201C>G p.R67= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, varscan2
- OBSCN | c.11659+4375G>T | Intron (SNP) | VAF 24/170 reads (14%) | catalogued as COSV99471753; called by muse, mutect2, varscan2
- OR2W5 | n.949C>T | RNA (SNP) | VAF 10/124 reads (8%) | catalogued as rs1417039453; called by muse, mutect2
- VMP1 | c.*1385_*1403del | 3'UTR (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
